Somatic mutation profile of tumor specimen 0DGDWF from CCDI case PBBTHI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.8 years (3,567 days).
Specimen 0DGDWF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48f4c1e5-36ea-4bf6-86f6-ceb343785815.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGDW2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/269fb3cd-2363-4c43-b014-d88f07128aad

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QTNF2 | c.218G>A p.R73Q (on ENST00000393975; = p.R28Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/428 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs375483575; called by muse, varscan2
- IFT172 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 103/644 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53131857; called by muse, varscan2
- LFNG | c.925G>A p.G309S (on ENST00000222725 / NM_001040167.2; = p.G180S on NM_002304.2) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs752829411; called by muse, varscan2
- SLC35F2 | c.145T>A p.L49M | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56184405; called by muse, varscan2
- C8B | c.1588C>A p.Q530K | Missense Mutation (SNP) | VAF 204/518 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, varscan2
- DCDC1 | c.4231G>C p.A1411P (on ENST00000597505 / NM_001367979.1; = p.A518P on NM_020869.3) | Missense Mutation (SNP) | VAF 97/618 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, varscan2
- KCND1 | c.1887C>A p.N629K | Missense Mutation (SNP) | VAF 186/470 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); called by muse, varscan2
- MUC16 | c.28894G>T p.A9632S | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.168); called by muse, varscan2
- INPP5E | c.1653G>A p.T551= | Silent (SNP) | VAF 157/345 reads (46%) | catalogued as rs1474030166, COSV65496222; called by muse, varscan2
- MAGI2 | c.411G>A p.T137= | Silent (SNP) | VAF 171/533 reads (32%) | catalogued as rs149568072, COSV100835566; ClinVar: uncertain significance; called by muse, varscan2
- GABRA6 | c.530-47C>G | Intron (SNP) | VAF 23/76 reads (30%) | called by muse, varscan2
- PSG11 | c.430+79G>C | Intron (SNP) | VAF 12/47 reads (26%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 12/120 reads (10%) | called by muse, varscan2
